Surgical pathology report (de-identified scan), TCGA case TCGA-SH-A9CU, project TCGA-MESO (Mesothelioma), tissue source site Papworth Hospital, specimen TCGA-SH-A9CU-01A (Primary Tumor).

HISTOPATHOLOGY REPORT

Sex: M

Date Collected:
Date Received:
Date Printed:

Copy To:

SPECIMEN DETAILS

Specimen A Pleurectomy decortication, Right pleura Tissue bank
Specimen B Pleura, parietal
Specimen C Pleura, parietal
Specimen D Visceral pleura
Specimen E Visceral pleura 2

ICD-O 3

*Mesothelioma, epithelioid, malignant # 965213
Site: Pleura NOS C38.4
2013/14*

CLINICAL INFORMATION

Known epithelioid malignant mesothelioma. Large piece of tissue please direct to in Pathology ASAP
SOBOE NYHA II. R pleural plaques --> biopsy --> Epithelioid type mesothelioma

MACROSCOPIC DESCRIPTION

Specimen A-Pleurectomy decortication, Right pleura Tissue bank

Pieces of thick cream pleura and some attached fat 6 x 5.5 x 2.5 cm in aggregate. Sample in 2 cassettes. 7 pieces in total

Specimen B-Pleura, parietal

Large pot labelled parietal pleura. A sheet of thickened pleura with attached fat 16 x 6.5 x 0.6 cm with a further piece of pleura and brown tissue 3 x 2 x 1 cm. Sampled in 1 cassette. (3 pieces)

Specimen C-Pleura, parietal

Piece of thickened pleura 4 cm in aggregate. Sampled in 1 cassette (4 pieces).

Specimen D-Visceral pleura

Pieces of thick pleura 5 x 2.5 x 0.5 cm and 5 x 2.5 x 0.5 cm. 4 pieces in 1 cassette.

Specimen E-Visceral pleura 2

Sheet of pleura 6.5 x 3.5 x up to 1.2 including a large surface nodule. 3 pieces sampled in 1 block.

MICROSCOPIC REPORT

Specimen A, B, C, D & E from parietal and visceral pleura

The sections show a malignant tumour formed of epithelioid cells which stain for calretinin in keeping with the previously diagnosed **epithelioid malignant mesothelioma**. The tumour has a solid and tubopapillary architecture. It invades through parietal pleural elastin into subpleural fat and through visceral pleural elastin into lung parenchyma. No sarcomatoid component is identified.

Reporting Pathologist:
Authorising Pathologist:

Dual/Synchronous Pathology Noted		

Source: NCI Genomic Data Commons file d0e7e0f1-9761-403a-bf8f-1339a6760a31 (TCGA-SH-A9CU.E4AE74A7-7144-41B1-A791-0FE1A00124E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).